Gene-level copy-number profile of tumor specimen TCGA-OR-A5JC-01A from TCGA case TCGA-OR-A5JC, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 38.0 years (13,862 days).
Specimen TCGA-OR-A5JC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.a8bbc616-f4a4-4133-9bc2-35a82c99829d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5JC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9a8910e2-f55e-4dab-9304-3b3192996729

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 2,618; copy number 2: 28,350; copy number 3: 12,563; copy number 4: 10,262; copy number 5: 3,102; copy number 6: 2,833; copy number 7: 80.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5JC-01A-11D-A29H-01): tumor purity 0.75, ploidy 2.77, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:28,800,683–29,191,808, 11 genes (within-gene range 0–1): Z93930.2, Z93930.3, Z93930.1, ZNRF3, ZNRF3-IT1, ZNRF3-AS1, C22orf31, KREMEN1, AL021393.1, RNU6-810P, RNU6-1219P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,009 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:1,173,141–2,262,023, 37 genes, copy number 5: CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, AC026748.7, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075, AC091849.2, SDHAP3, AC026412.3, AC091849.1, AC026412.1, AC026412.2, AC026412.4, MIR4277, AC112176.1, MRPL36, NDUFS6, AC025183.1, LINC02116, AC025183.2, IRX4, IRX4-AS1, CTD-2194D22.4, AC126768.3, AC124852.1, AC126768.1, AC126768.2, Y_RNA, AC092266.1.
- chr5:3,357,264–181,342,213, 2,898 genes, copy number 5–7 (broad region; genes not listed).
- chr6:36,740,775–37,175,428, 12 genes, copy number 6 (within-gene range 4–6): CPNE5, Z85996.2, Z85996.3, PPIL1, C6orf89, AL122034.1, PI16, MTCH1, FGD2, COX6A1P2, RPL12P2, PIM1.
- chr6:42,224,931–42,693,505, 4 genes, copy number 5 (within-gene range 4–5): TRERF1, AL591473.1, UBR2, RNU6-890P.
- chr8:140,940,562–141,308,305, 8 genes, copy number 6 (within-gene range 4–6): RNA5SP278, AC100860.1, DENND3, AC040970.1, SLC45A4, AC011676.5, AC011676.1, AC011676.2.
- chr12:66,767–133,214,832, 3,050 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,617. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
